TCGA case TCGA-IB-8126 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4387a2c2-8007-4735-a48c-34a2b476018e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 79 years; Vital status: Alive.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 80.0 years (29,213 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 462 days (1.3 years); Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 5; Lymph nodes tested: 10; Tumor largest dimension diameter: 3.5 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 103 days; Days to treatment end: 413 days (1.1 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Whipple.
2. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 80.2 years (29,296 days); Days to diagnosis: 83 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (4 entries)
- Days to follow up: 17 days; Disease response: With Tumor.
- Day 83 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 83 days; Evidence of progression type: Positive Biomarker(s).
- Days to follow up: 462 days (1.3 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 75.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Risk factors: Diabetes, NOS.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 4; Tobacco smoking onset year: 1957; Tobacco smoking quit year: 1961.
- Alcohol history: No; Alcohol intensity: Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IB-8126-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.5; Shortest dimension: 0.2.
  Slide TCGA-IB-8126-01A-01-TS1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 15; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 5.
  Slide TCGA-IB-8126-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 61; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 10.
- Sample TCGA-IB-8126-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IB-8126-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 3; Alcohol history documented: Yes; Diabetes diagnosis indicator: Yes; History chronic pancreatitis: No.
- Follow-up form 1: Lost to follow-up: Yes.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor.
- Drug treatment: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 462 days; disease-specific survival: no event (censored), 462 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 83 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IB-8126-01A-11D-2392-01): tumor purity 0.89, ploidy 2, whole-genome doublings 0.
